Somatic mutation profile of tumor specimen TCGA-CV-7089-01A (aliquot TCGA-CV-7089-01A-11D-2012-08) from TCGA case TCGA-CV-7089, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 74.3 years (27,149 days).
Specimen TCGA-CV-7089-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f6172ef-ba09-409c-acd3-5d168dc8c222.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7089-10A (Blood Derived Normal), aliquot TCGA-CV-7089-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80f065da-92e4-46d9-9bcd-a1c2414301f1

The open-access MAF lists 161 somatic variants for this specimen: 118 protein-altering or splice-affecting, 38 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 38, Nonsense Mutation 7, Intron 4, Splice Site 2, Frame Shift Ins 2, Frame Shift Del 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 17/75 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABL2 | c.3049G>C p.E1017Q (on ENST00000502732 / NM_007314.4; = p.E1002Q on NM_005158.5) | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.013); catalogued as COSV100772351; called by muse, mutect2, varscan2
- ADCY6 | c.2960A>G p.N987S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100326381; called by muse, mutect2, varscan2
- ADGRV1 | c.16752G>C p.E5584D | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs746339981, COSV101315397; called by muse, mutect2, varscan2
- AGTR1 | c.1002G>A p.M334I | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs778954862, COSV62558351; called by mutect2, varscan2
- ALDH3B2 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.595); catalogued as rs147016371; called by muse, mutect2, varscan2
- ALMS1 | c.12007G>A p.E4003K | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779308568, COSV100040974; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3355G>C p.E1119Q | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99781899; called by muse, mutect2
- ARHGAP31 | c.3406G>A p.E1136K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV51797173; called by muse, mutect2
- ARID1B | c.3395A>G p.Y1132C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99266794; called by muse, mutect2, varscan2
- ARSD | c.1699A>G p.I567V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as COSV101144053; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1380C>G p.I460M | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.447); catalogued as COSV100022553; called by muse, mutect2
- BPIFB2 | c.1159C>A p.L387I | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV99401085; called by muse, mutect2
- C1orf127 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV65438166; called by muse, mutect2, varscan2
- CCDC47 | c.628T>G p.S210A | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99853955; called by muse, mutect2, varscan2
- CCT2 | c.941A>T p.H314L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100167485; called by muse, mutect2, varscan2
- CEP152 | c.2483A>G p.K828R | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100358433; called by muse, mutect2, varscan2
- CMYA5 | c.5713C>G p.Q1905E | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV101483775; called by muse, mutect2, varscan2
- CPSF7 | c.30A>G p.I10M (on ENST00000394888 / NM_001136040.4; = p.I53M on NM_024811.4) | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as COSV100073862; called by muse, mutect2, varscan2
- CPT1B | c.1360G>C p.D454H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100376453; called by muse, mutect2, varscan2
- CTAGE1 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 28/309 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as COSV101194417; called by muse, mutect2
- CTSS | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV100934892; called by muse, mutect2, varscan2
- CWC22 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99843903; called by muse, mutect2, varscan2
- DLG5 | c.4384G>C p.E1462Q | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.608); catalogued as COSV100967224; called by muse, mutect2, varscan2
- DNAH11 | c.7574C>T p.A2525V | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.783); catalogued as COSV100176631; called by muse, mutect2
- ELN | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); catalogued as COSV99332174; called by muse, mutect2, varscan2
- EPN1 | c.1212C>A p.F404L (on ENST00000270460 / NM_001321263.1; = p.F378L on NM_013333.3) | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV50041451, COSV50044528; called by muse, mutect2, varscan2
- ETS1 | c.298A>G p.M100V | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.24); catalogued as COSV100089951; called by muse, mutect2, varscan2
- FAT1 | c.5980G>T p.E1994* | Nonsense Mutation (SNP) | VAF 105/358 reads (29%) | catalogued as COSV71673540, COSV71674847; called by muse, mutect2, varscan2
- FCGBP | c.10708G>A p.E3570K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1310511712; called by muse, mutect2, varscan2
- FGD6 | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 10/103 reads (10%) | catalogued as COSV100676326; called by muse, mutect2, varscan2
- GADD45GIP1 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1568456413, COSV100379776, COSV100380053; called by muse, mutect2, varscan2
- GATAD2A | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99389511; called by muse, mutect2
- GFI1B | c.222G>C p.R74S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV99044910; called by muse, mutect2, varscan2
- GPR158 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as rs1235084610, COSV66267181; called by muse, mutect2
- GPR3 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100927486; called by muse, mutect2, varscan2
- GPR37 | c.1018A>G p.I340V | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs761950961, COSV58259632; called by muse, mutect2, varscan2
- HCN4 | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.021); catalogued as COSV99983215; called by muse, mutect2
- HIVEP3 | c.4537C>T p.P1513S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56010548; called by muse, mutect2
- HUWE1 | c.4069C>T p.P1357S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as COSV53363786; called by muse, mutect2, varscan2
- HUWE1 | c.3946C>G p.Q1316E | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV99470454; called by muse, mutect2, varscan2
- ITGA3 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 41/298 reads (14%) | catalogued as COSV99143209; called by muse, mutect2, varscan2
- ITGAM | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV99791691; called by muse, mutect2, varscan2
- KBTBD12 | c.1182G>A p.M394I | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV59679437; called by muse, mutect2, varscan2
- KIAA0753 | c.1917G>C p.Q639H | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.639); catalogued as COSV100810518; called by muse, varscan2
- KLHL31 | c.1598T>C p.L533P | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100911716; called by muse, mutect2
- MAS1L | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs370775152; called by muse, mutect2, varscan2
- MAST1 | c.230C>G p.S77W | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52243982; called by muse, mutect2, varscan2
- MOV10 | c.1862C>T p.T621I | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1272567923, COSV99588064; called by muse, mutect2
- MUC7 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100512172; called by muse, mutect2, varscan2
- MYH1 | c.2561C>A p.A854D | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99874768, COSV99875026; called by muse, mutect2, varscan2
- NAALADL1 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV100367900; called by muse, mutect2, varscan2
- NCOR2 | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100656744; called by muse, mutect2, varscan2
- NCR1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as rs781129363, COSV99400723; called by muse, mutect2, varscan2
- NEK3 | c.1270C>G p.L424V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.101); catalogued as COSV51619760, COSV99317412; called by muse, mutect2, varscan2
- NOTCH1 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53053354, COSV53078940; called by muse, mutect2, varscan2
- NTM | c.245G>A p.W82* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as COSV66184585; called by muse, mutect2, varscan2
- OR4K15 | c.103G>A p.E35K (on ENST00000305051; = p.E11K on NM_001005486.1) | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV59303318; called by muse, mutect2, varscan2
- PCDH15 | c.1171C>G p.Q391E | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV100214401, COSV57387547; called by muse, mutect2, varscan2
- PDS5A | c.1126A>G p.I376V | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV100337131, COSV57831921; called by muse, mutect2, varscan2
- PIK3R4 | c.558C>G p.F186L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV100768174; called by muse, mutect2, varscan2
- PKDREJ | c.5285G>A p.R1762K | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.157); catalogued as COSV99478342; called by muse, varscan2
- PKDREJ | c.4969G>A p.E1657K | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV53552738; called by muse, mutect2, varscan2
- PKDREJ | c.4813G>C p.D1605H | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV99478350; called by muse, mutect2, varscan2
- PKDREJ | c.4636G>A p.D1546N | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV104387566, COSV99478351; called by muse, mutect2, varscan2
- PKDREJ | c.4272G>A p.M1424I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1165057525, COSV53549344, COSV53549368, COSV99478360; called by muse, varscan2
- POT1 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV62933987; called by muse, mutect2, varscan2
- POT1 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.575); catalogued as COSV100713986; called by muse, mutect2, varscan2
- PPP1R13B | c.323A>G p.N108S | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99157453; called by muse, mutect2, varscan2
- PPP1R16B | c.453G>C p.K151N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV100238903; called by muse, mutect2, varscan2
- PRICKLE2 | c.1414C>G p.L472V (on ENST00000295902; = p.L416V on NM_198859.4) | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.298); catalogued as COSV99896538; called by muse, mutect2, varscan2
- PROM2 | c.294+1G>T p.X98_splice | Splice Site (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100468593; called by muse, varscan2
- PROS1 | c.840G>C p.K280N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.203); catalogued as COSV101260203; called by muse, mutect2
- PSD4 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV99830784; called by muse, mutect2, varscan2
- PSMF1 | c.374A>G p.K125R | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.045); catalogued as rs377313597; called by muse, mutect2, varscan2
- PSRC1 | c.491C>G p.S164C | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV100883464; called by muse, mutect2, varscan2
- RAC3 | c.473C>G p.S158* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100141664; called by muse, mutect2
- RAG1 | c.2996C>G p.S999C | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100200623, COSV55024202; called by muse, mutect2, varscan2
- RUSC1 | c.1996G>C p.E666Q (on ENST00000368352 / NM_001105203.2; = p.E197Q on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.376); catalogued as COSV99429399; called by muse, mutect2, varscan2
- SAFB | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as COSV99412446; called by muse, mutect2, varscan2
- SCN1A | c.4418T>C p.F1473S (on ENST00000303395 / NM_001202435.3; = p.F1462S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100319097; called by muse, mutect2
- SEC31B | c.3042G>A p.M1014I | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100947191; called by muse, mutect2, varscan2
- SEPTIN3 | c.1011+6C>T | Splice Region (SNP) | VAF 11/79 reads (14%) | catalogued as rs765118631, COSV99351895; called by muse, mutect2, varscan2
- SH3KBP1 | c.545A>T p.E182V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV101114248; called by muse, mutect2, varscan2
- SLC25A25 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as rs1449487710, COSV100895247; called by muse, mutect2
- SLC26A2 | c.506G>T p.C169F | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53826855; called by muse, mutect2, varscan2
- SPINT2 | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV100007443, COSV56648939; called by muse, mutect2
- SUN3 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52048888, COSV99813780; called by muse, mutect2, varscan2
- TMEM177 | c.908G>C p.R303T | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV99733503; called by muse, mutect2, varscan2
- TSC2 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV99526074; called by muse, mutect2
- TTN | c.65842G>C p.E21948Q (on ENST00000591111; = p.E14524Q on NM_003319.4) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | PolyPhen benign (0.4); catalogued as rs776167958, COSV100592156; called by muse, mutect2, varscan2
- TULP4 | c.3707C>T p.S1236F | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as rs1195588706, COSV100893064; called by muse, mutect2, varscan2
- UGT1A6 | c.414C>G p.F138L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.1); catalogued as COSV100529405, COSV59389897; called by muse, mutect2, varscan2
- USP6 | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100002896; called by muse, mutect2, varscan2
- VPS13C | c.3142C>G p.Q1048E (on ENST00000644861 / NM_020821.3; = p.Q1005E on NM_017684.5) | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99826837; called by muse, mutect2, varscan2
- VPS50 | c.2832C>G p.I944M | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs1334469339, COSV100004447, COSV100004642; called by muse, mutect2, varscan2
- ZBTB38 | c.2694G>T p.E898D | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.877); catalogued as COSV100375209; called by muse, mutect2, varscan2
- ZC3H3 | c.1349G>A p.R450K | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV99367317; called by muse, mutect2
- ZMAT1 | c.454T>A p.L152I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.331); catalogued as COSV100858651; called by muse, mutect2, varscan2
- ZNF281 | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV99663962; called by muse, mutect2
- ZNF512B | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs371234637; called by muse, mutect2, varscan2
- ZNF568 | c.691T>G p.F231V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV100451134; called by muse, mutect2, varscan2
- ZNF610 | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV58347261; called by muse, mutect2, varscan2
- ZNF7 | c.1184C>G p.S395* | Nonsense Mutation (SNP) | VAF 7/91 reads (8%) | catalogued as COSV100295614; called by muse, mutect2
- ZNF77 | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV100094288; called by muse, mutect2
- ZNF782 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 33/244 reads (14%) | catalogued as COSV100001100; called by muse, mutect2, varscan2
- ZNF804B | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV60819214, COSV60861056; called by muse, mutect2, varscan2
- ZNF91 | c.1097C>A p.A366D | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as COSV100322040; called by muse, mutect2, varscan2
- ZWINT | c.615G>C p.K205N | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV100571474; called by muse, mutect2, varscan2
- ASXL1 | c.1779del p.C594Afs*109 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, varscan2
- BOP1 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CFAP74 | c.1446G>C p.K482N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); called by muse, mutect2
- DAAM1 | c.1139del p.F380Sfs*26 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- IGHA1 | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); called by muse, mutect2
- IL1RAP | c.1136dup p.H379Qfs*19 | Frame Shift Ins (INS) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- PIP4K2B | c.828C>G p.I276M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- RBM5 | c.1614_1617+1del p.X538_splice | Splice Site (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel
- TCEAL3 | c.129dup p.C44Mfs*8 | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- ACVRL1 | c.807G>A p.S269= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs1332822854, COSV66359506; called by muse, mutect2, varscan2
- ADCY7 | c.2877C>A p.A959= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99575628; called by mutect2, varscan2
- AKR7A2 | c.846C>T p.A282= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs963724504, COSV52516268; called by muse, mutect2, varscan2
- AP3D1 | c.3045G>A p.Q1015= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1471204444, COSV100642369; called by muse, mutect2, varscan2
- BEND2 | c.1851T>G p.S617= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV101191743; called by muse, mutect2, varscan2
- BMPER | c.1467C>G p.L489= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV51822986, COSV99778763; called by muse, mutect2, varscan2
- C12orf54 | c.282G>A p.L94= | Silent (SNP) | VAF 12/139 reads (9%) | catalogued as rs933140361, COSV100011493; called by muse, mutect2
- CCDC151 | c.1449C>T p.F483= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs367797540; called by muse, mutect2, varscan2
- CRY1 | c.240A>G p.P80= | Silent (SNP) | VAF 28/175 reads (16%) | catalogued as COSV99150324; called by muse, mutect2, varscan2
- CYP4F11 | c.1209G>A p.T403= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as rs988550925, COSV99930526; called by muse, mutect2, varscan2
- FAM111B | c.331C>T p.L111= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100639220; called by muse, mutect2, varscan2
- FCGBP | c.10092G>A p.Q3364= | Silent (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- GP5 | c.981G>C p.L327= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100540576; called by muse, mutect2
- HLA-DOA | c.693C>T p.G231= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as COSV100008073; called by muse, mutect2, varscan2
- HTR3C | c.1323C>G p.V441= | Silent (SNP) | VAF 26/229 reads (11%) | catalogued as COSV100570471; called by muse, mutect2, varscan2
- IPO13 | c.1977T>C p.D659= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV100961029; called by muse, mutect2, varscan2
- KCNB2 | c.1449C>T p.D483= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as rs555669570, COSV73051774; called by muse, mutect2
- KIAA1109 | c.10125A>G p.A3375= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs759456425, COSV52691433, COSV99145588; called by muse, mutect2, varscan2
- KRT39 | c.153C>T p.L51= | Silent (SNP) | VAF 42/304 reads (14%) | catalogued as COSV100842159; called by muse, mutect2, varscan2
- MNDA | c.1032T>C p.N344= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs1411842518, COSV100933229; called by muse, mutect2, varscan2
- NBPF3 | c.888C>T p.L296= | Silent (SNP) | VAF 32/273 reads (12%) | catalogued as COSV59057986; called by muse, mutect2, varscan2
- OR4D6 | c.330A>G p.A110= | Silent (SNP) | VAF 25/200 reads (13%) | catalogued as COSV100271537; called by muse, mutect2, varscan2
- OR5F1 | c.438C>T p.A146= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs756447954, COSV53545224, COSV99558526; called by muse, mutect2, varscan2
- PKDREJ | c.6735G>A p.G2245= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV99478336; called by muse, mutect2
- PKDREJ | c.5175G>A p.L1725= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV99478345; called by muse, varscan2
- PKDREJ | c.4356G>A p.Q1452= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as COSV99478352; called by muse, varscan2
- PLAUR | c.462A>G p.E154= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as COSV99654958; called by muse, mutect2, varscan2
- RAC3 | c.334C>T p.L112= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs1407372390, COSV100141663; called by muse, mutect2, varscan2
- RBM12B | c.1770T>C p.P590= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV101234462; called by muse, mutect2, varscan2
- RSRC2 | c.1113G>A p.L371= | Silent (SNP) | VAF 16/147 reads (11%) | catalogued as COSV100063279; called by muse, mutect2
- STK33 | c.1515C>T p.G505= | Silent (SNP) | VAF 39/262 reads (15%) | catalogued as rs752970888, COSV59403477; called by muse, mutect2, varscan2
- SYNE2 | c.12159A>G p.K4053= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs1018982085, COSV100646544; called by muse, mutect2, varscan2
- TAF1L | c.2604C>T p.C868= | Silent (SNP) | VAF 21/190 reads (11%) | catalogued as rs146604611, COSV54267193; called by muse, mutect2, varscan2
- TRMT11 | c.1113C>T p.V371= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100543047; called by muse, mutect2, varscan2
- TSPOAP1 | c.1479C>A p.T493= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV99269856; called by muse, mutect2, varscan2
- UNC13B | c.78G>A p.L26= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV101036149, COSV101037462; called by muse, mutect2, varscan2
- USH2A | c.14319C>T p.S4773= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as rs1382011754, COSV100228290; called by muse, mutect2, varscan2
- UVSSA | c.1212C>T p.D404= | Silent (SNP) | VAF 23/202 reads (11%) | catalogued as rs778612037, COSV101104287; called by muse, mutect2, varscan2
- DCHS2 | n.1695G>A | RNA (SNP) | VAF 9/94 reads (10%) | catalogued as COSV100250739; called by muse, mutect2, varscan2
- EML2 | c.21-139G>A | Intron (SNP) | VAF 8/51 reads (16%) | catalogued as COSV55601955; called by muse, mutect2, varscan2
- LAMB4 | c.5146+2149G>C | Intron (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99222510; called by muse, mutect2, varscan2
- ZNF783 | c.802+3013G>A | Intron (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100954094; called by muse, mutect2, varscan2
- ZSCAN32 | c.839-615G>A | Intron (SNP) | VAF 18/158 reads (11%) | catalogued as COSV100514126; called by muse, mutect2, varscan2
